Somatic mutation profile of tumor specimen TARGET-10-PARSUV-09A (aliquot TARGET-10-PARSUV-09A-01D) from TARGET case TARGET-10-PARSUV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.4 years (6,714 days).
Specimen TARGET-10-PARSUV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) badfbe08-928e-4435-a4bc-05b2c21f7fcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSUV-14A (Bone Marrow Normal), aliquot TARGET-10-PARSUV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6e0ce96-7bac-49a9-8b62-c33a96ca1e6a

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GPT2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs1205102812, COSV60840409; called by muse, mutect2, varscan2
- IVL | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as rs1200437952; called by muse, mutect2, varscan2
- MYH6 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs757728653, COSV62450095; called by muse, mutect2, varscan2
- MYLK3 | c.1669G>A p.V557M | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs369679573; called by muse, mutect2, varscan2
- TSKU | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs573127395; called by muse, mutect2, varscan2
- ZNF462 | c.6902G>A p.R2301H | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs771701909, COSV52935232; called by muse, mutect2, varscan2
- DCHS2 | c.1946T>G p.V649G | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MAPK8IP2 | c.1741G>A p.V581I | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NR3C1 | c.1907T>C p.L636P | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2
- SMTNL2 | c.448A>G p.N150D (on ENST00000389313 / NM_001114974.2; = p.N6D on NM_198501.3) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B4 | c.2427A>C p.V809= | Silent (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- PNMA2 | c.960G>A p.P320= | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as rs375621804; called by muse, mutect2, varscan2
- TENM2 | c.342C>T p.D114= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as COSV72855268; called by muse, mutect2, varscan2
- ATP10A | c.449+392dup | Intron (INS) | VAF 28/70 reads (40%) | called by mutect2, pindel*, varscan2*
- CLEC2L | c.266-31G>A | Intron (SNP) | VAF 9/18 reads (50%) | catalogued as rs766263224; called by muse, varscan2
- IFI35 | c.-48_-47insC | 5'UTR (INS) | VAF 29/78 reads (37%) | called by mutect2, pindel*, varscan2
